Gene-level copy-number profile of tumor specimen TCGA-BR-8059-01A from TCGA case TCGA-BR-8059, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.5 years (26,474 days).
Specimen TCGA-BR-8059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.436e754f-8cfb-46e8-a2f1-2648f56098dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8059-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a110f41f-df7b-40e9-9ac4-60d2b03329e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 5,815; copy number 2: 37,695; copy number 3: 10,093; copy number 4: 4,887; copy number 5: 1,115; copy number 6: 115.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8059-01A-11D-2338-01): tumor purity 0.37, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–62,297,609, 3 genes (within-gene range 0–1): PTPRG, Y_RNA, RPL10AP6.
- chr4:179,856,853–180,574,027, 4 genes: AC021193.1, AC108169.1, AC096747.1, NDUFB5P1.
- chr4:183,987,669–184,625,030, 18 genes (within-gene range 0–1): AC074194.1, AC074194.2, AC107222.1, ENPP6, AC107222.2, AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, AC099343.3, LINC02427, AC099343.1, LINC02365.
- chr9:21,304,326–25,089,151, 56 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr16:79,077,376–79,110,882, 3 genes: AC009145.3, AC009145.1, AC009145.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,230 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 3–5): RYR2.
- chr1:237,471,119–248,919,946, 272 genes, copy number 5 (broad region; genes not listed).
- chr3:149,917,342–174,378,005, 360 genes, copy number 5–6 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr4:72,280,969–78,008,688, 118 genes, copy number 5 (broad region; genes not listed).
- chr4:78,180,866–78,182,046, 1 gene, copy number 5: SERBP1P5.
- chr6:7,258,910–13,711,835, 106 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:125,466,939–137,425,021, 142 genes, copy number 5 (broad region; genes not listed).
- chr11:84,887,207–93,438,487, 178 genes, copy number 5 (broad region; genes not listed).
- chr16:7,126,293–10,227,581, 50 genes, copy number 5: AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P.
- chr16:10,351,440–10,352,752, 1 gene, copy number 5: AC131649.1.

Autosomal genes at a single copy (total copy number 1): 3,402. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
